TARGET case TARGET-30-PAMPCU — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Hematopoietic and reticuloendothelial systems. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/ea7fe49a-2e43-530f-bc53-e88ea2b7b147

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (872 days); Year of diagnosis: 2003; Days to last follow up: 4,543 days (12.4 years); INSS stage: Stage 4.
